Somatic mutation profile of tumor specimen C3L-01700-54 (aliquot CPT0200690002) from CPTAC case C3L-01700, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 69.7 years (25,452 days).
Specimen C3L-01700-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7050b2f3-cbd3-4f94-9092-beaf37de3121.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01700-51 (Buccal Cell Normal), aliquot CPT0200790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f73ada8e-e9a1-4e12-a36d-5e8a2a056b4e

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND5B | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1200226104, COSV60907541; called by muse, mutect2, varscan2
- KCNJ16 | c.1254G>A p.M418I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1375377462, COSV52255175; called by muse, mutect2, varscan2
- LDLRAD3 | c.454+3529G>A | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as rs557847537; called by muse, varscan2
